Gene-level copy-number profile of tumor specimen TCGA-QL-A97D-01A from TCGA case TCGA-QL-A97D, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 84.6 years (30,914 days).
Specimen TCGA-QL-A97D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d41e0f93-8a32-4197-b19d-ee4594875703.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QL-A97D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4452694-032a-4e87-900e-8a200bc6d39b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 39; copy number 2: 7,558; copy number 3: 21,406; copy number 4: 26,218; copy number 5: 1,443; copy number 6: 1,749; copy number 7: 59; copy number 8: 537; copy number 9: 751; copy number 10: 40; copy number 11: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QL-A97D-01A-12D-A40O-01): tumor purity 0.59, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:77,915,870–77,918,011, 1 gene: LINC01851.
- chr16:6,703,883–6,748,969, 3 genes: AC007012.2, AC007012.1, RNU7-99P.
- chr17:11,874,727–12,021,508, 4 genes: AC005209.1, AC005410.2, ZNF18, AC005410.1.
- chr17:12,036,496–12,036,637, 1 gene: RNU11-2P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 801 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:19,201,637–65,973,699, 770 genes, copy number 9–10 (broad region; genes not listed).
- chr13:79,872,586–83,298,167, 21 genes, copy number 10: LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P.
- chr20:57,957,126–58,515,399, 10 genes, copy number 11 (within-gene range 6–11): AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L.

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
